Somatic mutation profile of tumor specimen MP2PRT-PAVFSA-TBP1-A (aliquot MP2PRT-PAVFSA-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVFSA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (862 days).
Specimen MP2PRT-PAVFSA-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e26c1fc8-074c-45e1-b5c7-faf130af5403.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFSA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFSA-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a8c45fd-2704-4f92-b107-222f6f322dbf

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, 5'Flank 2, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 50/273 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CLPB | c.162del p.R55Afs*186 | Frame Shift Del (DEL) | VAF 157/674 reads (23%) | catalogued as rs756188595; called by mutect2, pindel, varscan2
- HRH3 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 163/524 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs556427489; called by muse, mutect2, varscan2
- KRT19 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 124/531 reads (23%) | catalogued as rs761448167, COSV54179285; called by muse, mutect2, varscan2
- MAEA | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 99/422 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs550232745; called by muse, mutect2, varscan2
- OR2C1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 131/425 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs147461021, COSV59241320; called by muse, mutect2, varscan2
- PCDHB2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 125/369 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs782596400, COSV99523824; called by muse, mutect2, varscan2
- SCEL | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34794176; called by muse, mutect2, varscan2
- CTCF | c.521_522dup p.V175Rfs*5 | Frame Shift Ins (INS) | VAF 108/392 reads (28%) | called by mutect2, pindel, varscan2
- PTPRB | c.2547T>A p.Y849* | Nonsense Mutation (SNP) | VAF 104/367 reads (28%) | called by muse, mutect2, varscan2
- STK11IP | c.1055A>C p.E352A | Missense Mutation (SNP) | VAF 119/405 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ADGRL3 | c.2673C>T p.Y891= (on ENST00000506720 / NM_001322402.2; = p.Y823= on NM_015236.6) | Silent (SNP) | VAF 64/314 reads (20%) | called by muse, mutect2, varscan2
- LAMA1 | c.6084C>T p.D2028= | Silent (SNP) | VAF 127/590 reads (22%) | catalogued as rs773172566, COSV101058047; called by muse, mutect2, varscan2
- MAP1B | c.5211C>T p.T1737= | Silent (SNP) | VAF 83/321 reads (26%) | called by muse, mutect2, varscan2
- OGT | c.1206A>C p.G402= | Silent (SNP) | VAF 96/375 reads (26%) | called by muse, mutect2, varscan2
- TAF1L | c.69G>A p.S23= | Silent (SNP) | VAF 69/224 reads (31%) | catalogued as rs777403013, COSV54260834; called by muse, mutect2, varscan2
- ADGRA1 | chr10:133084844 C>T | 5'Flank (SNP) | VAF 38/618 reads (6%) | catalogued as rs367784257; called by muse, mutect2
- QRICH2 | chr17:76307777 G>A | 5'Flank (SNP) | VAF 173/699 reads (25%) | called by muse, mutect2, varscan2
